Somatic mutation profile of tumor specimen ALCH-B0CC-TTP1-A (aliquot ALCH-B0CC-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0CC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.0 years (25,583 days).
Specimen ALCH-B0CC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f28e338-5692-4fa0-bee3-720fbc8c3854.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0CC-NB1-A (Blood Derived Normal), aliquot ALCH-B0CC-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04d9a530-e0c9-4c0a-b305-0439f880ad10

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD24 | c.2795G>A p.R932Q | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.547); catalogued as rs1318289774, COSV53667534; called by muse, mutect2
- NRXN3 | c.1369T>C p.Y457H (on ENST00000335750 / NM_001330195.2; = p.Y84H on NM_004796.6) | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.996); catalogued as rs920708474; called by muse, mutect2, varscan2
- SMG8 | c.595A>C p.S199R | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as rs549105150; called by muse, mutect2, varscan2
- STC2 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 102/584 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273720400; called by muse, mutect2, varscan2
- ZNF479 | c.1418C>A p.A473D | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs782114478; called by muse, mutect2, varscan2
- GRIA1 | c.2485T>A p.C829S | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- IDS | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 53/494 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- MSH3 | c.1183C>A p.P395T | Missense Mutation (SNP) | VAF 113/528 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB3 | c.470C>G p.A157G | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PRKAG1 | c.362A>G p.Y121C | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- UCMA | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.732); called by muse, mutect2
- BCLAF3 | c.522G>A p.L174= | Silent (SNP) | VAF 12/300 reads (4%) | called by muse, mutect2
- C3 | c.3249C>T p.V1083= | Silent (SNP) | VAF 28/167 reads (17%) | called by muse, mutect2, varscan2
- MUC5B | c.1053C>T p.R351= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs376020643; called by muse, mutect2, varscan2
- SLC20A1 | c.1419C>T p.D473= | Silent (SNP) | VAF 16/306 reads (5%) | catalogued as rs878944586; called by muse, mutect2
- CHRNB1 | c.463-47C>T | Intron (SNP) | VAF 24/210 reads (11%) | catalogued as COSV53441381; called by muse, mutect2, varscan2
- SSPOP | n.10462C>T | RNA (SNP) | VAF 16/100 reads (16%) | catalogued as rs780317234, COSV65137785; called by muse, varscan2
